Somatic mutation profile of tumor specimen MBCProject_3692_T1_WES (aliquot MBCProject_3692_T1_WES_1) from CMI case MBCProject_3692, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.8 years (14,910 days).
Specimen MBCProject_3692_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef4c76a3-7dc9-4762-ad61-9cc58938f744.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3692_SALIVA (Saliva), aliquot MBCProject_3692_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/807ec929-a842-4a07-9e70-726176dc8d16

The open-access MAF lists 86 somatic variants for this specimen: 40 protein-altering or splice-affecting, 15 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Intron 20, Silent 15, 3'UTR 4, 5'Flank 4, Nonsense Mutation 3, RNA 2, Splice Region 1, Frame Shift Del 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOK5 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1416515891, COSV52824901; called by mutect2, varscan2
- FAM47C | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63729435; called by muse, mutect2, varscan2
- GUK1 | c.-168G>T | Splice Region (SNP) | VAF 12/89 reads (13%) | catalogued as rs745382729; called by mutect2, varscan2
- HERC2 | c.14078G>T p.G4693V | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1342849221; called by muse, mutect2, varscan2
- HSPA6 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.117); catalogued as COSV100553755, COSV59061575; called by muse, mutect2, varscan2
- KCNQ4 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100714377; called by muse, mutect2, varscan2
- NIN | c.3772G>C p.E1258Q | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV55379501, COSV55405801; called by muse, mutect2, varscan2
- RASGRP3 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1486351349; called by muse, mutect2
- RPL11 | c.296C>T p.S99L (on ENST00000374550 / NM_001199802.1; = p.S100L on NM_000975.5) | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs11556036, COSV65778420; called by mutect2, varscan2
- SUMF1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs147405528; called by muse, mutect2, varscan2
- TNRC6B | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs763244893; called by muse, mutect2, varscan2
- TXNRD2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183950022; ClinVar: uncertain significance; called by muse, mutect2
- VBP1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1489872460; called by muse, mutect2
- ZKSCAN3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs201098027, COSV52852042; called by mutect2, varscan2
- ZNF74 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs772198434, COSV100677540; called by mutect2, varscan2
- AC109583.1 | c.828C>G p.F276L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS8 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- AKR1C8P | c.404del p.D135Vfs*8 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, varscan2
- ANGPTL1 | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD27 | c.1578dup p.N527Qfs*33 | Frame Shift Ins (INS) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- BHLHE40 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2
- BNC1 | c.1668G>C p.E556D | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRWD3 | c.1690C>T p.L564F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CCDC18 | c.2092G>T p.G698W (on ENST00000343253 / NM_001306076.1; = p.G699W on NM_206886.4) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- HSPBP1 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 27/220 reads (12%) | called by muse, varscan2
- IFIT3 | c.1104G>C p.Q368H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- IFT140 | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- KAT2A | c.1815C>A p.H605Q | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- KLHL34 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGALS3BP | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NUP160 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- OLFM4 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHGB5 | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3R4 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
- PLA2G7 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.105); called by muse, mutect2
- SAAL1 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- SPRED1 | c.763A>T p.I255L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TECTA | c.3878G>C p.G1293A | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.206); called by mutect2, varscan2
- TMEM98 | c.116A>T p.Q39L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- XK | c.885G>C p.W295C | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKFN1 | c.2778G>C p.L926= (on ENST00000653862; = p.L779= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/118 reads (30%) | called by muse, mutect2, varscan2
- APBB3 | c.1131C>T p.I377= (on ENST00000357560 / NM_133173.2; = p.I384= on NM_006051.3) | Silent (SNP) | VAF 23/188 reads (12%) | catalogued as rs768312092; called by muse, mutect2, varscan2
- CNN3 | c.210G>A p.V70= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- CNTN6 | c.72C>T p.S24= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs920928960, COSV63183394; called by mutect2, varscan2
- ENAM | c.759T>A p.S253= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- FAM120C | c.2178C>A p.L726= | Silent (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- GALNT17 | c.1614C>T p.L538= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs182957380; called by mutect2, varscan2
- IGFL1 | c.30C>G p.V10= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV71443603; called by muse, mutect2, varscan2
- KALRN | c.7323G>A p.T2441= (on ENST00000360013 / NM_001024660.4; = p.T744= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs371007725; called by mutect2, varscan2
- LAG3 | c.1566G>C p.P522= | Silent (SNP) | VAF 15/160 reads (9%) | catalogued as rs1443195395; called by muse, mutect2
- LHCGR | c.147C>T p.A49= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1209432761; called by muse, mutect2
- PTGR1 | c.873C>G p.V291= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as COSV53031205; called by muse, mutect2, varscan2
- SLCO4A1 | c.943C>T p.L315= | Silent (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- SPEN | c.1215G>A p.Q405= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV65365398; called by muse, mutect2, varscan2
- ZNF750 | c.1000A>C p.R334= | Silent (SNP) | VAF 60/354 reads (17%) | called by muse, mutect2, varscan2
- AC022517.1 | chr19:5174050 A>C | 5'Flank (SNP) | VAF 27/239 reads (11%) | catalogued as rs1228929187; called by muse, varscan2
- ADAT1 | c.238+613A>C | Intron (SNP) | VAF 12/112 reads (11%) | catalogued as rs1187792420; called by muse, mutect2
- AL138759.1 | n.208-2799A>G | Intron (SNP) | VAF 8/70 reads (11%) | catalogued as rs1413802823; called by muse, mutect2
- ANKS1B | c.2886+83G>A | Intron (SNP) | VAF 8/38 reads (21%) | catalogued as rs765772439; called by mutect2, varscan2
- CDIPT | chr16:29864851 C>A | 5'Flank (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- CEACAM1 | c.1246+2118A>G | Intron (SNP) | VAF 16/149 reads (11%) | catalogued as rs1302692901; called by mutect2, varscan2
- CSF2RA | c.*174A>G | 3'UTR (SNP) | VAF 8/46 reads (17%) | catalogued as rs746260224; called by muse, varscan2
- DCHS2 | n.6483C>T | RNA (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100601009; called by mutect2, varscan2
- DCHS2 | n.20G>A | RNA (SNP) | VAF 10/55 reads (18%) | catalogued as rs557099840, COSV59720320; called by mutect2, varscan2
- DDIAS | chr11:82913986 A>G | 5'Flank (SNP) | VAF 6/59 reads (10%) | catalogued as rs1386717589; called by muse, varscan2
- EDRF1 | c.2371+161A>G | Intron (SNP) | VAF 6/54 reads (11%) | catalogued as rs1299179669; called by muse, varscan2
- ETNK2 | c.519-750G>T | Intron (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- GDA | c.578+799A>G | Intron (SNP) | VAF 10/59 reads (17%) | catalogued as rs1407015218; called by muse, varscan2
- HK1 | c.28-3301T>C | Intron (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2
- IL6R | c.949+1428T>C | Intron (SNP) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- LACTB2 | c.286+744T>C | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- MYBPC1 | chr12:101685660 C>G | 3'Flank (SNP) | VAF 16/87 reads (18%) | catalogued as rs1318865270; called by muse, mutect2, varscan2
- OSTC | c.432-3997T>C | Intron (SNP) | VAF 21/176 reads (12%) | catalogued as rs1329162440; called by muse, varscan2
- PFKM | c.85+2515G>C | Intron (SNP) | VAF 14/109 reads (13%) | catalogued as rs1436506039; called by muse, varscan2
- PIP5K1B | c.1502+22451A>G | Intron (SNP) | VAF 23/160 reads (14%) | catalogued as rs1291087826; called by muse, varscan2
- PNPO | c.364-32A>T | Intron (SNP) | VAF 30/448 reads (7%) | called by muse, mutect2
- RBL2 | c.993-400A>G | Intron (SNP) | VAF 30/248 reads (12%) | catalogued as rs1426585233; called by muse, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 28/196 reads (14%) | catalogued as rs910081914; called by muse, mutect2
- RNU7-174P | chr8:80559488 C>G | 5'Flank (SNP) | VAF 18/321 reads (6%) | called by muse, mutect2
- SLC41A3 | c.274-5450G>A | Intron (SNP) | VAF 7/65 reads (11%) | catalogued as rs367939630; called by mutect2, varscan2
- TCEANC2 | c.*8172T>G | 3'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as rs1299122292; called by mutect2, varscan2
- THEM4 | c.287-807A>G | Intron (SNP) | VAF 20/298 reads (7%) | catalogued as rs1483716190, COSV64296099; called by muse, mutect2
- TPH1 | c.*1262G>A | 3'UTR (SNP) | VAF 18/138 reads (13%) | called by muse, varscan2
- UMPS | c.*1333T>G | 3'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs1339329329; called by muse, varscan2
- YBX1 | c.166+288C>T | Intron (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- ZNF273 | c.326-4267T>C | Intron (SNP) | VAF 26/224 reads (12%) | called by muse, varscan2
